Somatic mutation profile of tumor specimen MMRF_2650_1_BM_CD138pos (aliquot MMRF_2650_1_BM_CD138pos_T1_KHS5U_L13768) from MMRF case MMRF_2650, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 59.1 years (21,579 days).
Specimen MMRF_2650_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af9f44be-b6a4-4d52-99cc-95de4d8dbafe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2650_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2650_1_PB_WBC_C3_KHS5U_L13769; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60aebbb1-21eb-4d5a-80ad-597c4233f1be

The open-access MAF lists 109 somatic variants for this specimen: 37 protein-altering or splice-affecting, 14 silent, 58 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Intron 21, 3'UTR 20, Silent 14, 5'UTR 7, 3'Flank 5, Nonsense Mutation 4, Splice Site 3, 5'Flank 3, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARNT | c.1222C>G p.L408V | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV62232333; called by muse, mutect2
- CACNB2 | c.1714G>T p.E572* (on ENST00000324631 / NM_201596.3; = p.E517* on NM_000724.4) | Nonsense Mutation (SNP) | VAF 25/395 reads (6%) | catalogued as rs539824188, COSV56634203; called by muse, mutect2
- CCDC73 | c.2434C>G p.Q812E | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.51); catalogued as COSV58803213; called by muse, mutect2, varscan2
- CFAP99 | c.204G>C p.L68F (on ENST00000506607; = p.L553F on NM_001193282.3) | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.533); catalogued as rs554631738; called by muse, mutect2, varscan2
- DDI2 | c.388C>T p.Q130* | Nonsense Mutation (SNP) | VAF 17/219 reads (8%) | catalogued as rs1416854324, COSV100197657; called by muse, mutect2
- EFCAB12 | c.1405-1G>A p.X469_splice (on ENST00000326085; = p.K468= on NM_207307.3) | Splice Site (SNP) | VAF 7/144 reads (5%) | catalogued as COSV100394878; called by muse, mutect2
- ERICH3 | c.1861C>A p.Q621K | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.406); catalogued as COSV58598332, COSV58614939; called by muse, mutect2
- GFM2 | c.2028+1G>C p.X676_splice | Splice Site (SNP) | VAF 20/233 reads (9%) | catalogued as COSV54666858; called by muse, mutect2
- MDFIC | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs1362372654, COSV57566700; called by muse, mutect2
- MUC16 | c.37165C>A p.P12389T | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.897); catalogued as rs1053561174; called by muse, mutect2
- NEB | c.17073G>T p.K5691N | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV51087277; called by muse, mutect2
- NIN | c.3715G>C p.E1239Q | Missense Mutation (SNP) | VAF 17/237 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55383036; called by muse, mutect2
- RPE65 | c.1579C>T p.H527Y | Missense Mutation (SNP) | VAF 32/514 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779073856; called by muse, mutect2
- RSPH6A | c.179G>A p.R60K | Missense Mutation (SNP) | VAF 19/201 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as rs1279602673; called by muse, mutect2, varscan2
- SPDYC | c.253G>C p.D85H | Missense Mutation (SNP) | VAF 7/176 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV65865264; called by muse, mutect2
- STARD9 | c.3589C>G p.Q1197E | Missense Mutation (SNP) | VAF 13/182 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.143); catalogued as rs1274788382; called by muse, mutect2
- ZNF469 | c.8909G>A p.R2970Q (on ENST00000437464; = p.R2998Q on NM_001367624.2) | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.629); catalogued as rs1165825244, COSV71259163; called by muse, mutect2, varscan2
- DARS2 | c.1390G>T p.E464* | Nonsense Mutation (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- DSE | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.149); called by muse, mutect2
- EFCAB12 | c.36C>G p.F12L | Missense Mutation (SNP) | VAF 10/306 reads (3%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2
- FAM169A | c.1601C>G p.S534* | Nonsense Mutation (SNP) | VAF 26/280 reads (9%) | called by muse, mutect2
- GRID2IP | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- LCT | c.5096C>T p.S1699F | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.345); called by muse, mutect2
- LRRC8D | c.2095C>G p.P699A | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MMUT | c.1523C>T p.T508I | Missense Mutation (SNP) | VAF 4/90 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.163); called by muse, mutect2
- MYH10 | c.3132G>C p.K1044N | Missense Mutation (SNP) | VAF 34/398 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.821); called by muse, mutect2
- NCAPH | c.2047G>A p.D683N | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.018); called by muse, mutect2
- OTOF | c.3259G>A p.D1087N (on ENST00000272371 / NM_194248.3; = p.D340N on NM_004802.4) | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); called by muse, mutect2
- PDE6C | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 17/250 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- PLCB3 | c.2039-1G>C p.X680_splice | Splice Site (SNP) | VAF 16/287 reads (6%) | called by muse, mutect2
- SH2B2 | c.1963G>A p.E655K | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.116); called by muse, mutect2
- SHB | c.925G>C p.D309H | Missense Mutation (SNP) | VAF 7/166 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.28); called by muse, mutect2
- SLC44A4 | c.400C>G p.Q134E | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TAF6L | c.1841C>G p.S614W | Missense Mutation (SNP) | VAF 22/292 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); called by muse, mutect2
- TRIOBP | c.6284C>T p.S2095F (on ENST00000644935 / NM_001039141.3; = p.S382F on NM_007032.5) | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.24); called by muse, mutect2
- USP9X | c.7669G>A p.E2557K | Missense Mutation (SNP) | VAF 18/380 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); called by muse, mutect2
- ZNF257 | c.43C>G p.L15V | Missense Mutation (SNP) | VAF 16/290 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.654); called by muse, mutect2
- CLEC14A | c.42C>G p.L14= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as rs1471835388; called by muse, mutect2
- EFHD1 | c.114C>G p.P38= | Silent (SNP) | VAF 11/34 reads (32%) | called by muse, mutect2, varscan2
- ESPN | c.879G>A p.V293= | Silent (SNP) | VAF 4/53 reads (8%) | called by muse, mutect2
- FAM171A2 | c.114G>T p.P38= | Silent (SNP) | VAF 6/79 reads (8%) | called by muse, mutect2
- FIBCD1 | c.141C>A p.V47= | Silent (SNP) | VAF 10/166 reads (6%) | called by muse, mutect2
- GUCY2C | c.42C>T p.L14= | Silent (SNP) | VAF 8/198 reads (4%) | called by muse, mutect2
- IL17REL | c.663G>A p.L221= | Silent (SNP) | VAF 12/281 reads (4%) | called by muse, mutect2
- IL22RA1 | c.822G>A p.P274= | Silent (SNP) | VAF 8/107 reads (7%) | catalogued as rs143248338, COSV54629146; called by muse, mutect2
- MEGF8 | c.4803C>T p.L1601= (on ENST00000251268 / NM_001271938.2; = p.L1534= on NM_001410.3) | Silent (SNP) | VAF 8/109 reads (7%) | called by muse, mutect2
- PLOD1 | c.1188G>A p.L396= | Silent (SNP) | VAF 8/128 reads (6%) | called by muse, mutect2
- RSBN1L | c.1770G>A p.L590= | Silent (SNP) | VAF 16/304 reads (5%) | called by muse, mutect2
- UNC93B1 | c.696C>T p.F232= | Silent (SNP) | VAF 24/270 reads (9%) | catalogued as rs766090062; called by muse, mutect2
- ZNF792 | c.564C>T p.I188= | Silent (SNP) | VAF 22/355 reads (6%) | catalogued as COSV68692724; called by muse, mutect2
- ZSCAN32 | c.1161C>T p.F387= (on ENST00000396846; = p.F408= on NM_017810.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 14/180 reads (8%) | catalogued as rs1181364879; called by muse, mutect2
- AC022182.1 | n.732C>G | RNA (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- ATP2B2 | c.*2472G>C | 3'UTR (SNP) | VAF 14/204 reads (7%) | called by muse, mutect2
- ATP8B1 | c.1221-29C>T | Intron (SNP) | VAF 10/64 reads (16%) | catalogued as COSV52181147; called by mutect2, varscan2
- BCAN | c.2209+49C>G | Intron (SNP) | VAF 14/211 reads (7%) | catalogued as rs1418745638; called by muse, mutect2
- BIRC3 | c.*1330G>A | 3'UTR (SNP) | VAF 8/48 reads (17%) | called by mutect2, varscan2
- C17orf49 | chr17:7014651 G>C | 5'Flank (SNP) | VAF 14/280 reads (5%) | catalogued as rs1186441106; called by muse, mutect2
- C1QTNF9 | c.*621C>T | 3'UTR (SNP) | VAF 7/54 reads (13%) | catalogued as rs866142651; called by muse, mutect2
- CANX | chr5:179698582 C>T | 5'Flank (SNP) | VAF 14/424 reads (3%) | called by muse, mutect2
- CIITA | c.2657+118G>A | Intron (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- CRYBG1 | c.*3222C>T | 3'UTR (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2, varscan2
- CSH1 | c.-55C>G | 5'UTR (SNP) | VAF 22/468 reads (5%) | called by muse, mutect2
- CSNK1G1 | c.*4392C>T | 3'UTR (SNP) | VAF 9/171 reads (5%) | called by muse, mutect2
- CYP2U1 | c.*2111C>T | 3'UTR (SNP) | VAF 15/159 reads (9%) | called by muse, mutect2, varscan2
- DUSP22 | c.508+589C>G | Intron (SNP) | VAF 21/716 reads (3%) | called by muse, mutect2
- EMSY | c.1363+34C>T | Intron (SNP) | VAF 7/152 reads (5%) | called by muse, mutect2
- ERCC8 | chr5:60873817 G>A | 3'Flank (SNP) | VAF 11/54 reads (20%) | called by mutect2, varscan2
- ERLIN1 | chr10:100150819 G>A | 3'Flank (SNP) | VAF 5/85 reads (6%) | catalogued as rs1289282739; called by muse, mutect2
- FAM172A | c.*1785G>A | 3'UTR (SNP) | VAF 12/204 reads (6%) | called by muse, mutect2
- FAM3C | c.*101C>T | 3'UTR (SNP) | VAF 18/327 reads (6%) | catalogued as COSV100739850; called by muse, mutect2
- FERMT1 | c.*365G>A | 3'UTR (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- HNF4A | c.115+1096G>C | Intron (SNP) | VAF 8/86 reads (9%) | called by muse, mutect2
- HOXA7 | c.*784C>A | 3'UTR (SNP) | VAF 6/131 reads (5%) | called by muse, mutect2
- HSD17B11 | c.-29del | 5'UTR (DEL) | VAF 4/38 reads (11%) | catalogued as rs748608537; called by pindel, varscan2
- IL18 | c.91+49G>C | Intron (SNP) | VAF 4/57 reads (7%) | called by muse, mutect2
- INPP4B | c.373-32693C>G | Intron (SNP) | VAF 11/140 reads (8%) | called by muse, mutect2
- ITGA5 | c.1914+38G>A | Intron (SNP) | VAF 19/225 reads (8%) | catalogued as rs1024253335; called by muse, mutect2
- KIF5A | c.2992+122C>T | Intron (SNP) | VAF 7/45 reads (16%) | called by muse, mutect2
- KLHL18 | c.129+14576G>C | Intron (SNP) | VAF 13/226 reads (6%) | called by muse, mutect2
- KRT20 | c.*163G>C | 3'UTR (SNP) | VAF 8/229 reads (3%) | catalogued as rs971882124; called by muse, mutect2
- LIN9 | c.244+331G>A | Intron (SNP) | VAF 6/95 reads (6%) | catalogued as rs1037417120; called by muse, mutect2
- LPP | c.1240+3155G>A | Intron (SNP) | VAF 7/98 reads (7%) | called by muse, mutect2
- LRRC27 | chr10:132379479 G>A | 3'Flank (SNP) | VAF 17/96 reads (18%) | catalogued as rs1292248416; called by muse, mutect2, varscan2
- MIR4272 | n.41C>G | RNA (SNP) | VAF 5/136 reads (4%) | called by muse, mutect2
- MIR4710 | chr14:104681517 T>C | 5'Flank (SNP) | VAF 8/150 reads (5%) | catalogued as rs1275034499; called by muse, mutect2
- NTRK2 | c.-316G>C | 5'UTR (SNP) | VAF 19/319 reads (6%) | called by muse, mutect2
- OR8B3 | chr11:124396289 G>C | 3'Flank (SNP) | VAF 7/76 reads (9%) | called by muse, mutect2
- POU6F2 | chr7:39465988 G>A | 3'Flank (SNP) | VAF 16/147 reads (11%) | called by muse, mutect2, varscan2
- PRKAG2 | c.685-65G>A | Intron (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.929+6174G>C | Intron (SNP) | VAF 14/258 reads (5%) | catalogued as rs1296852219; called by muse, mutect2
- PSD4 | c.*678C>T | 3'UTR (SNP) | VAF 19/310 reads (6%) | called by muse, mutect2
- PTPN14 | c.-119C>G | 5'UTR (SNP) | VAF 8/112 reads (7%) | called by muse, mutect2
- RNASE6 | c.*199G>C | 3'UTR (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- SCN4B | c.*895C>G | 3'UTR (SNP) | VAF 10/109 reads (9%) | called by muse, mutect2
- SEMA6A | c.1730-346G>C | Intron (SNP) | VAF 7/182 reads (4%) | called by muse, mutect2
- SIX6 | c.-211C>T | 5'UTR (SNP) | VAF 5/48 reads (10%) | catalogued as rs1308258425; called by muse, mutect2
- SLC1A7 | c.432-2755C>G | Intron (SNP) | VAF 9/94 reads (10%) | catalogued as rs541411920; called by muse, mutect2
- SLC35F3 | c.*720G>A | 3'UTR (SNP) | VAF 12/118 reads (10%) | called by muse, mutect2
- SPINK5 | c.602+58G>A | Intron (SNP) | VAF 5/87 reads (6%) | called by muse, mutect2
- SSRP1 | c.*391G>A | 3'UTR (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2
- TAFA1 | c.*61C>G | 3'UTR (SNP) | VAF 23/467 reads (5%) | called by muse, mutect2
- TAZ | c.647-37C>A | Intron (SNP) | VAF 26/306 reads (8%) | called by muse, mutect2
- TGIF1 | c.-233C>T | 5'UTR (SNP) | VAF 7/143 reads (5%) | catalogued as rs1568048802; called by muse, mutect2
- TMBIM6 | c.-31+378C>G | Intron (SNP) | VAF 9/216 reads (4%) | catalogued as rs1207452099; called by muse, mutect2
- TMEM268 | c.*2448C>G | 3'UTR (SNP) | VAF 5/79 reads (6%) | called by muse, mutect2
- TNFRSF1B | c.*1095C>T | 3'UTR (SNP) | VAF 40/620 reads (6%) | called by muse, mutect2
- TRIOBP | c.6324+727C>T | Intron (SNP) | VAF 9/92 reads (10%) | called by muse, mutect2
- UNC45B | c.*2179G>A | 3'UTR (SNP) | VAF 5/65 reads (8%) | called by muse, mutect2
- ZNF878 | c.-94C>T | 5'UTR (SNP) | VAF 19/481 reads (4%) | called by muse, mutect2
